Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3561, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3561-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with ulcerated colon carcinoma of the histological type of a moderately differentiated colorectal adenocarcinoma, located in the area of the passage between the cecum and ascending colon, encircling the intestinal wall and measuring 4.5 cm in length. Invasive spreading of the tumor within all intestinal wall layers to the bordering mesocolic adipose tissue.

Appendix with fibrous obliteration of the lumen.

Tumor-free oral and aboral resection margin as well as greater omentum. Fifty lymph nodes in the region tumor-free with uncharacteristically reactive changes.

Tumor stage therefore pT3 pN0 (0/50) LO0 V0: G2 R0.

Source: NCI Genomic Data Commons file 7860fdb5-f4ab-4d9f-824b-711f56d00ddd (TCGA-AA-3561.6F8B8558-C90F-45FA-9A89-6F35B3C118A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).